Gene-level copy-number profile of tumor specimen TCGA-AA-A01Z-01A from TCGA case TCGA-AA-A01Z, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 68.4 years (24,990 days).
Specimen TCGA-AA-A01Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.696d23b9-6a6c-464a-bf8e-fd2e897fe737.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01Z-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45cef3ab-f24c-4cfc-9b82-d289e05f30f3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,081; copy number 2: 47,872; copy number 3: 4,266; copy number 4: 73; copy number 5: 14; copy number 6: 384; copy number 9: 50; copy number 12: 19; copy number 14: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A01Z-01A-11D-A080-01): tumor purity 0.81, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 519 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:127,295,620–142,106,747, 328 genes, copy number 6 (broad region; genes not listed).
- chr7:143,132,077–144,098,953, 51 genes, copy number 6: PIP, TAS2R39, AC073342.1, TAS2R40, AC073342.2, GSTK1, TMEM139-AS1, TMEM139, CASP2, RN7SL535P, RN7SL481P, HINT1P1, CLCN1, FAM131B, AC093673.2, AC093673.1, ZYX, MIR6892, EPHA1, EPHA1-AS1, TAS2R62P, TAS2R60, TAS2R41, OR2R1P, OR10AC1, AC073264.1, PAICSP5, CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C, RNU6-267P, CTAGE6, AC099548.2, PAICSP6, AC099548.1, TCAF2P1, TCAF1, OR2F2, OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1, OR2A5, OR2A25, OR2A41P, OR2A12.
- chr8:37,597,480–37,700,019, 5 genes, copy number 6: AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703.
- chr15:101,653,596–101,933,350, 14 genes, copy number 12 (within-gene range 1–12): TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:57,912,333–57,922,581, 1 gene, copy number 9: AC015845.1.
- chr17:65,457,541–70,629,265, 106 genes, copy number 9–14 (broad region; genes not listed).
- chr21:18,269,116–19,345,312, 14 genes, copy number 5 (within-gene range 3–5): TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.

Autosomal genes at a single copy (total copy number 1): 7,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
